Somatic mutation profile of cancer-model specimen HCM-CSHL-0155-C50-85D (3D Organoid, passage 17; aliquot HCM-CSHL-0155-C50-85D-01D-A82H-36), derived from the primary tumor of HCMI case HCM-CSHL-0155-C50, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Tumor grade: GX; Age at diagnosis: 49.0 years (17,880 days).
Specimen HCM-CSHL-0155-C50-85D: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 17.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e80502a-708f-43f7-b6b1-f15f2736adb0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0155-C50-10A (Blood Derived Normal), aliquot HCM-CSHL-0155-C50-10A-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d52e6f42-547e-4b12-b536-4475cf932e47

The open-access MAF lists 291 somatic variants for this specimen: 204 protein-altering or splice-affecting, 75 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 173, Silent 75, Nonsense Mutation 16, Intron 5, Splice Site 4, RNA 3, Frame Shift Del 3, In Frame Del 2, 3'UTR 2, Frame Shift Ins 2, In Frame Ins 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMPD1 | c.1464G>A p.W488* | Nonsense Mutation (SNP) | VAF 128/362 reads (35%) | catalogued as rs1447749222; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- H3C2 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 195/634 reads (31%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen benign (0.323); catalogued as COSV52517971, COSV52518546; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 156/514 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 180/180 reads (100%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS16 | c.2974G>A p.A992T | Missense Mutation (SNP) | VAF 165/593 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs751536987, COSV56996986; called by muse, mutect2, varscan2
- AKR7A3 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 134/216 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.546); catalogued as rs756610725, COSV64389201; called by muse, mutect2, varscan2
- AMER1 | c.923C>A p.P308Q | Missense Mutation (SNP) | VAF 251/1117 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs143958560, COSV57668565; ClinVar: benign; called by muse, mutect2, varscan2
- AP000721.1 | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 294/875 reads (34%) | PolyPhen possibly damaging (0.856); catalogued as rs1359236732; called by muse, mutect2, varscan2
- ARHGAP9 | c.1609+1G>T p.X537_splice (on ENST00000393797 / NM_001319850.2; = p.X518_splice on NM_032496.4) | Splice Site (SNP) | VAF 166/268 reads (62%) | catalogued as rs1484949856; called by muse, mutect2, varscan2
- BRIP1 | c.400C>G p.L134V | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as CM1512696, COSV51994417; called by muse, mutect2, varscan2
- BTBD3 | c.1073C>G p.P358R | Missense Mutation (SNP) | VAF 136/517 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99656041; called by muse, mutect2, varscan2
- C8orf82 | c.650G>C p.*217Sext*151 | Nonstop Mutation (SNP) | VAF 242/2327 reads (10%) | catalogued as rs1403442286; called by muse, mutect2, varscan2
- CNTN5 | c.503C>G p.S168C | Missense Mutation (SNP) | VAF 90/299 reads (30%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.806); catalogued as COSV99677387, COSV99679149; called by muse, mutect2, varscan2
- CRACD | c.1799G>A p.G600D | Missense Mutation (SNP) | VAF 199/942 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51715745; called by muse, mutect2, varscan2
- DCANP1 | c.519G>C p.L173F | Missense Mutation (SNP) | VAF 141/474 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs745525886; called by muse, mutect2, varscan2
- DCST1 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 262/1014 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.433); catalogued as rs760441746, COSV55051025; called by muse, mutect2, varscan2
- DHRS2 | c.543G>A p.A181= | Splice Region (SNP) | VAF 340/340 reads (100%) | catalogued as rs765882203, COSV51633303, COSV99161316; called by muse, mutect2, varscan2
- DNAH10 | c.488T>C p.F163S (on ENST00000409039; = p.F102S on NM_207437.3) | Missense Mutation (SNP) | VAF 97/306 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV68987616; called by muse, mutect2, varscan2
- DNAJC9 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 292/1197 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.36); catalogued as rs1356780140; called by muse, mutect2, varscan2
- EPB41 | c.2416-1G>C p.X806_splice (on ENST00000343067 / NM_001166005.2; = p.X530_splice on NM_004437.4) | Splice Site (SNP) | VAF 129/190 reads (68%) | catalogued as COSV58040877; called by muse, mutect2, varscan2
- ERBB2 | c.1550G>A p.R517Q | Missense Mutation (SNP) | VAF 663/12167 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs759579850; called by muse, mutect2
- FAM135B | c.1576G>T p.A526S | Missense Mutation (SNP) | VAF 136/310 reads (44%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV52702447; called by mutect2, varscan2
- FAT1 | c.2344C>T p.R782C | Missense Mutation (SNP) | VAF 213/518 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs556690116; called by muse, mutect2, varscan2
- FZD2 | c.1653C>G p.F551L | Missense Mutation (SNP) | VAF 155/311 reads (50%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.976); catalogued as COSV59530207; called by muse, mutect2, varscan2
- G6PD | c.1417G>C p.E473Q | Missense Mutation (SNP) | VAF 328/754 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as COSV100855113; called by mutect2, varscan2
- GALNT13 | c.1276C>T p.R426C | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as rs150203694; called by muse, mutect2, varscan2
- GAS6 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 182/366 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781147555, COSV59849567; called by muse, mutect2, varscan2
- GDF6 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 169/1374 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); catalogued as rs1447166633, COSV54626185; called by muse, mutect2, varscan2
- GLMP | c.1159G>C p.G387R | Missense Mutation (SNP) | VAF 227/976 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.176); catalogued as rs1223559820, COSV55295018; called by muse, mutect2, varscan2
- GLUD2 | c.1523C>G p.S508C | Missense Mutation (SNP) | VAF 172/724 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100046567, COSV60151969; called by muse, mutect2, varscan2
- H3C2 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 214/706 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.08); catalogued as COSV52518439, COSV52519759; called by muse, mutect2, varscan2
- IGFLR1 | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 249/766 reads (33%) | catalogued as rs1005277772; called by muse, mutect2, varscan2
- IQCD | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 176/627 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1314142566; called by muse, mutect2, varscan2
- IQCE | c.1450C>G p.L484V | Missense Mutation (SNP) | VAF 460/642 reads (72%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as rs1349745353; called by muse, mutect2, varscan2
- MAML1 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 234/761 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.019); catalogued as rs770524065; called by muse, mutect2, varscan2
- MARS2 | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 126/525 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs1039051691; called by muse, mutect2, varscan2
- MCC | c.2329G>C p.E777Q | Missense Mutation (SNP) | VAF 116/346 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56728153; called by muse, mutect2, varscan2
- MTARC1 | c.226G>C p.E76Q | Missense Mutation (SNP) | VAF 178/911 reads (20%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.802); catalogued as rs775260812; called by muse, mutect2, varscan2
- MUC17 | c.3061A>G p.S1021G | Missense Mutation (SNP) | VAF 451/452 reads (100%) | SIFT tolerated (0.09); PolyPhen benign (0.092); catalogued as COSV100072884; called by muse, mutect2, varscan2
- MUC4 | c.7444C>G p.L2482V | Missense Mutation (SNP) | VAF 161/2246 reads (7%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.374); catalogued as COSV100640295, COSV100640520; called by muse, mutect2
- NAB1 | c.748C>T p.R250W | Missense Mutation (SNP) | VAF 80/361 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as rs1053176, COSV61609598; called by muse, mutect2, varscan2
- NEB | c.13489G>C p.E4497Q | Missense Mutation (SNP) | VAF 206/320 reads (64%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV51449521; called by muse, mutect2, varscan2
- NPRL2 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 99/232 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.241); catalogued as rs1453959857; called by muse, mutect2, varscan2
- NR3C2 | c.1952G>A p.R651Q | Missense Mutation (SNP) | VAF 35/302 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100679295; called by muse, mutect2, varscan2
- NR4A2 | c.1025G>C p.R342T | Missense Mutation (SNP) | VAF 124/424 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59892963; called by muse, mutect2, varscan2
- NTSR2 | c.488C>G p.S163W | Missense Mutation (SNP) | VAF 300/1361 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as COSV60991230; called by muse, mutect2, varscan2
- OTOF | c.4297C>T p.R1433W (on ENST00000272371 / NM_194248.3; = p.R666W on NM_004802.4) | Missense Mutation (SNP) | VAF 380/778 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769051185, COSV99718472; called by muse, mutect2, varscan2
- PCDH1 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 171/812 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as rs1223161926; called by muse, mutect2, varscan2
- PKDCC | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 300/1129 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as rs766142478, COSV99684802; called by muse, mutect2, varscan2
- PPM1E | c.1494T>G p.S498R | Missense Mutation (SNP) | VAF 122/744 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV57574986; called by muse, mutect2, varscan2
- PRICKLE3 | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 337/343 reads (98%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs782354019; called by muse, mutect2, varscan2
- PRR22 | c.983C>T p.S328L | Missense Mutation (SNP) | VAF 226/449 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as rs751915954; called by muse, mutect2, varscan2
- PXDN | c.3790C>T p.Q1264* | Nonsense Mutation (SNP) | VAF 153/706 reads (22%) | catalogued as COSV53234653; called by muse, mutect2, varscan2
- RBMXL3 | c.1756G>A p.G586R | Missense Mutation (SNP) | VAF 220/1018 reads (22%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); catalogued as rs782358096; called by muse, mutect2, varscan2
- RFC3 | c.991C>T p.H331Y | Missense Mutation (SNP) | VAF 150/308 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1426651599; called by muse, mutect2, varscan2
- RHPN1 | c.1813G>A p.V605I | Missense Mutation (SNP) | VAF 169/348 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs368945775; called by muse, mutect2, varscan2
- RUBCN | c.1624C>T p.R542W | Missense Mutation (SNP) | VAF 148/1112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754358548, COSV56364971; called by muse, mutect2, varscan2
- SAMD14 | c.134G>C p.R45P | Missense Mutation (SNP) | VAF 269/1325 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53309210; called by muse, mutect2, varscan2
- SCAF1 | c.3112G>A p.E1038K | Missense Mutation (SNP) | VAF 302/1272 reads (24%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.723); catalogued as COSV100862143; called by muse, varscan2
- SCARB2 | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 112/486 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); catalogued as rs1316817158; called by muse, mutect2, varscan2
- SEL1L2 | c.1958G>A p.R653K | Missense Mutation (SNP) | VAF 179/279 reads (64%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs770442031, COSV53157989; called by muse, mutect2, varscan2
- SHROOM3 | c.5695G>T p.D1899Y | Missense Mutation (SNP) | VAF 247/539 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56029428; called by muse, mutect2, varscan2
- SIRT1 | c.2113G>A p.E705K | Missense Mutation (SNP) | VAF 139/643 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.054); catalogued as rs778261267; called by muse, mutect2, varscan2
- SLC15A3 | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 402/632 reads (64%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs779627240; called by muse, mutect2, varscan2
- SPANXN2 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 242/970 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.067); catalogued as rs1390452648, COSV65128478; called by muse, mutect2, varscan2
- STEAP4 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 63/225 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777525378; called by muse, mutect2, varscan2
- STK3 | c.612C>G p.I204M | Missense Mutation (SNP) | VAF 305/1307 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs1262074313; called by muse, mutect2, varscan2
- SUN1 | c.1166G>A p.G389D (on ENST00000405266 / NM_001367651.1; = p.G269D on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 197/419 reads (47%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as rs1020606766, COSV100568677; called by muse, mutect2, varscan2
- TEDC2 | c.1118G>A p.R373Q | Missense Mutation (SNP) | VAF 297/1150 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.211); catalogued as rs752195413, COSV62523034; called by muse, mutect2, varscan2
- TIMM8B | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 213/615 reads (35%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs1352755224, COSV54777145; called by muse, mutect2, varscan2
- TRIM68 | c.1080G>T p.W360C | Missense Mutation (SNP) | VAF 183/374 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1216932015; called by muse, mutect2, varscan2
- TTC22 | c.250G>T p.E84* | Nonsense Mutation (SNP) | VAF 287/973 reads (29%) | catalogued as COSV64882047; called by muse, mutect2, varscan2
- TTN | c.11482G>C p.E3828Q (on ENST00000591111; = p.E3782Q on NM_003319.4) | Missense Mutation (SNP) | VAF 291/460 reads (63%) | catalogued as COSV100592054; called by muse, mutect2, varscan2
- TTN | c.9640G>A p.D3214N (on ENST00000591111; = p.D3168N on NM_003319.4) | Missense Mutation (SNP) | VAF 187/302 reads (62%) | PolyPhen probably damaging (0.998); catalogued as rs778326573, COSV60237511; called by muse, mutect2, varscan2
- UNC13A | c.4588G>A p.V1530I | Missense Mutation (SNP) | VAF 148/327 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.218); catalogued as rs1332635668; called by muse, mutect2, varscan2
- USP54 | c.3134C>T p.S1045F | Missense Mutation (SNP) | VAF 155/791 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.365); catalogued as COSV60444498; called by muse, mutect2, varscan2
- VPS13B | c.2345C>G p.S782C | Missense Mutation (SNP) | VAF 35/311 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.443); catalogued as COSV62017008; called by muse, mutect2, varscan2
- VWDE | c.1214G>A p.W405* | Nonsense Mutation (SNP) | VAF 92/182 reads (51%) | catalogued as COSV51735294; called by muse, mutect2
- WDR12 | c.655+1G>A p.X219_splice | Splice Site (SNP) | VAF 21/74 reads (28%) | catalogued as rs1384232411; called by muse, mutect2, varscan2
- YME1L1 | c.674T>C p.L225S (on ENST00000326799 / NM_139312.3; = p.L168S on NM_014263.4) | Missense Mutation (SNP) | VAF 210/430 reads (49%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs1290442325; called by muse, mutect2, varscan2
- ZNF436 | c.424C>T p.H142Y | Missense Mutation (SNP) | VAF 138/379 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs936099841; called by muse, mutect2, varscan2
- ZNF580 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 323/1473 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as rs1397268412, COSV54401240; called by muse, mutect2, varscan2
- ZNF761 | c.964G>T p.E322* | Nonsense Mutation (SNP) | VAF 143/315 reads (45%) | catalogued as COSV61888244; called by muse, mutect2, varscan2
- ABCC2 | c.442C>T p.Q148* | Nonsense Mutation (SNP) | VAF 79/288 reads (27%) | called by muse, mutect2, varscan2
- ACAA2 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 100/224 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- ACP2 | c.409C>A p.Q137K | Missense Mutation (SNP) | VAF 332/872 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- ACVR1 | c.815C>G p.S272* | Nonsense Mutation (SNP) | VAF 67/228 reads (29%) | called by muse, mutect2, varscan2
- ADAMTS14 | c.2229G>C p.Q743H | Missense Mutation (SNP) | VAF 155/587 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ADAP1 | c.638A>T p.E213V | Missense Mutation (SNP) | VAF 126/575 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.427); called by muse, mutect2, varscan2
- AFDN | c.4478G>C p.R1493T | Missense Mutation (SNP) | VAF 199/617 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- AL121899.2 | c.1246dup p.R416Pfs*51 | Frame Shift Ins (INS) | VAF 187/566 reads (33%) | called by mutect2, pindel, varscan2
- ANKRD24 | c.2300del p.R767Lfs*243 | Frame Shift Del (DEL) | VAF 361/861 reads (42%) | called by mutect2, pindel, varscan2
- APOBEC3C | c.490G>C p.D164H | Missense Mutation (SNP) | VAF 40/310 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ART3 | c.1045C>T p.P349S (on ENST00000355810 / NM_001377173.1; = p.P338S on NM_001179.6) | Missense Mutation (SNP) | VAF 99/452 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.903); called by muse, mutect2
- ATP8A2 | c.1376A>G p.E459G | Missense Mutation (SNP) | VAF 94/206 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.402); called by muse, mutect2, varscan2
- B3GNT2 | c.856_858del p.K286del | In Frame Del (DEL) | VAF 236/534 reads (44%) | called by pindel, varscan2
- BCO1 | c.1325C>A p.T442K | Missense Mutation (SNP) | VAF 98/504 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- BLM | c.3914G>C p.R1305T | Missense Mutation (SNP) | VAF 149/550 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- C2orf80 | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 87/153 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CABS1 | c.323G>C p.R108T | Missense Mutation (SNP) | VAF 79/363 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CACNA1C | c.5467G>A p.D1823N | Missense Mutation (SNP) | VAF 314/488 reads (64%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CBY3 | c.601G>C p.E201Q | Missense Mutation (SNP) | VAF 272/780 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- CCDC88A | c.109G>C p.D37H | Missense Mutation (SNP) | VAF 312/629 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- CCDC88C | c.4426G>T p.G1476W | Missense Mutation (SNP) | VAF 143/527 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- CCT5 | c.755C>T p.T252I | Missense Mutation (SNP) | VAF 116/418 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD52 | c.71C>G p.S24* | Nonsense Mutation (SNP) | VAF 145/413 reads (35%) | called by muse, mutect2, varscan2
- CDV3 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 201/956 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.1); called by muse, varscan2
- CEP126 | c.2399C>G p.P800R | Missense Mutation (SNP) | VAF 87/240 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CEP295 | c.225A>C p.Q75H | Missense Mutation (SNP) | VAF 92/318 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CEP295 | c.226A>T p.T76S | Missense Mutation (SNP) | VAF 92/316 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CHST7 | c.341C>G p.S114W | Missense Mutation (SNP) | VAF 302/304 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COPB2 | c.1384G>C p.E462Q | Missense Mutation (SNP) | VAF 49/410 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- CRACR2A | c.412G>C p.E138Q | Missense Mutation (SNP) | VAF 149/515 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- CYFIP2 | c.1010G>A p.S337N | Missense Mutation (SNP) | VAF 124/438 reads (28%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- CYP21A2 | c.499C>G p.L167V | Missense Mutation (SNP) | VAF 247/802 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DENND2C | c.536G>C p.R179T | Missense Mutation (SNP) | VAF 45/183 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- DLEU7 | c.225G>C p.R75S | Missense Mutation (SNP) | VAF 163/389 reads (42%) | SIFT tolerated (0.7); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNAH14 | c.10166C>G p.S3389* (on ENST00000445597; = p.S4397* on NM_001367479.1) | Nonsense Mutation (SNP) | VAF 78/361 reads (22%) | called by muse, mutect2, varscan2
- DNHD1 | c.1846G>A p.E616K | Missense Mutation (SNP) | VAF 77/179 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- DST | c.20875G>C p.E6959Q (on ENST00000361203 / NM_001374722.1; = p.E4656Q on NM_015548.5) | Missense Mutation (SNP) | VAF 170/276 reads (62%) | SIFT tolerated (0.45); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- DUSP9 | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 174/812 reads (21%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.481); called by mutect2, varscan2
- DYNC2I2 | c.1130C>G p.S377C | Missense Mutation (SNP) | VAF 300/937 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- ENDOV | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 175/429 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, varscan2
- ERCC4 | c.1973G>A p.R658K | Missense Mutation (SNP) | VAF 113/528 reads (21%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- F8 | c.5027C>T p.S1676L | Missense Mutation (SNP) | VAF 108/504 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- FANCF | c.251A>C p.Q84P | Missense Mutation (SNP) | VAF 298/593 reads (50%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- FGFBP2 | c.578G>C p.G193A | Missense Mutation (SNP) | VAF 154/341 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- FKBP9 | c.1597G>C p.D533H | Missense Mutation (SNP) | VAF 44/876 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.603); called by muse, mutect2
- GDAP2 | c.1337C>T p.S446L | Missense Mutation (SNP) | VAF 120/367 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GLP1R | c.689T>G p.F230C | Missense Mutation (SNP) | VAF 170/474 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- GLTPD2 | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 365/366 reads (100%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- HELZ | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 72/485 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- HFE | c.180C>G p.F60L | Missense Mutation (SNP) | VAF 194/527 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- HRNR | c.5687G>T p.S1896I | Missense Mutation (SNP) | VAF 190/3225 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.282); called by muse, mutect2
- IDO1 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 100/764 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- IGFL3 | c.357G>C p.R119S | Missense Mutation (SNP) | VAF 233/467 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- INTS1 | c.5806C>G p.L1936V | Missense Mutation (SNP) | VAF 415/842 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IRX3 | c.442G>T p.E148* | Nonsense Mutation (SNP) | VAF 294/917 reads (32%) | called by muse, mutect2, varscan2
- KIAA0100 | c.2535G>C p.Q845H | Missense Mutation (SNP) | VAF 21/622 reads (3%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.99); called by muse, mutect2
- KMT2A | c.400G>A p.G134R | Missense Mutation (SNP) | VAF 309/963 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KMT2A | c.1822C>T p.R608* | Nonsense Mutation (SNP) | VAF 137/437 reads (31%) | called by muse, mutect2, varscan2
- LONRF3 | c.705G>C p.K235N | Missense Mutation (SNP) | VAF 970/1298 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- LRRC45 | c.1438_1440del p.R480del | In Frame Del (DEL) | VAF 164/408 reads (40%) | called by mutect2, pindel, varscan2
- LSM4 | c.162G>C p.W54C | Missense Mutation (SNP) | VAF 190/390 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- MAS1L | c.514T>A p.C172S | Missense Mutation (SNP) | VAF 277/824 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- MEGF8 | c.3122C>G p.S1041* (on ENST00000251268 / NM_001271938.2; = p.S974* on NM_001410.3) | Nonsense Mutation (SNP) | VAF 160/562 reads (28%) | called by muse, mutect2, varscan2
- MYO1E | c.3247G>C p.E1083Q | Missense Mutation (SNP) | VAF 88/159 reads (55%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- MYO5A | c.4852G>C p.E1618Q | Missense Mutation (SNP) | VAF 143/317 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- NDC1 | c.1788G>C p.L596F | Missense Mutation (SNP) | VAF 76/276 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- NDE1 | c.24C>G p.F8L | Missense Mutation (SNP) | VAF 171/442 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- NOTCH4 | c.4256G>A p.G1419E | Missense Mutation (SNP) | VAF 316/1016 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- NRSN1 | c.106G>T p.D36Y | Missense Mutation (SNP) | VAF 289/458 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- ONECUT3 | c.735C>G p.F245L | Missense Mutation (SNP) | VAF 295/612 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- OR4K3 | c.313C>T p.H105Y | Missense Mutation (SNP) | VAF 227/779 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR5M1 | c.223T>C p.S75P | Missense Mutation (SNP) | VAF 137/429 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- OR6N1 | c.126C>A p.N42K | Missense Mutation (SNP) | VAF 183/754 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OSBPL6 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 81/315 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PA2G4 | c.1162G>C p.E388Q | Missense Mutation (SNP) | VAF 88/315 reads (28%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.051); called by muse, varscan2
- PAPLN | c.316T>C p.W106R | Missense Mutation (SNP) | VAF 470/470 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.147); called by muse, varscan2
- PAPLN | c.643G>C p.E215Q | Missense Mutation (SNP) | VAF 203/629 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PHACTR4 | c.1898T>C p.V633A (on ENST00000373839 / NM_001350159.2; = p.V643A on NM_023923.4) | Missense Mutation (SNP) | VAF 216/335 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- PLEKHH2 | c.4297-1G>C p.X1433_splice | Splice Site (SNP) | VAF 68/271 reads (25%) | called by muse, mutect2, varscan2
- POLK | c.2321G>C p.G774A | Missense Mutation (SNP) | VAF 85/189 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- PPP1R12B | c.862G>C p.D288H | Missense Mutation (SNP) | VAF 111/476 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PRDM14 | c.629C>A p.T210N | Missense Mutation (SNP) | VAF 164/756 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- PRKACA | c.-1_20del | Translation Start Site (DEL) | VAF 110/314 reads (35%) | called by mutect2, varscan2
- PRKCSH | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 105/240 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- PSME4 | c.2146C>G p.L716V | Missense Mutation (SNP) | VAF 105/468 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- RAG1 | c.2230C>G p.L744V | Missense Mutation (SNP) | VAF 142/294 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RBM44 | c.668C>G p.S223C (on ENST00000611254; = p.S857C on NM_001080504.2) | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.49); called by muse, mutect2
- RFX6 | c.872del p.L291Yfs*53 | Frame Shift Del (DEL) | VAF 39/174 reads (22%) | called by mutect2, pindel, varscan2
- RPE65 | c.28G>A p.G10S | Missense Mutation (SNP) | VAF 124/411 reads (30%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- RUFY3 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SCYGR1 | c.42_43insCGTTGTGGTGGC p.G14_C15insRCGG | In Frame Ins (INS) | VAF 26/230 reads (11%) | called by mutect2, pindel*
- SECISBP2 | c.1219G>C p.E407Q | Missense Mutation (SNP) | VAF 84/237 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- SLC12A5 | c.1594C>G p.L532V (on ENST00000454036 / NM_001134771.2; = p.L509V on NM_020708.5) | Missense Mutation (SNP) | VAF 145/454 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- SLC6A19 | c.1256T>C p.L419P | Missense Mutation (SNP) | VAF 198/649 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SOX3 | c.797G>T p.G266V | Missense Mutation (SNP) | VAF 727/1429 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SP5 | c.315C>G p.F105L | Missense Mutation (SNP) | VAF 338/977 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SPHKAP | c.4513G>T p.E1505* | Nonsense Mutation (SNP) | VAF 169/567 reads (30%) | called by muse, mutect2, varscan2
- SPINK1 | c.230G>T p.G77V | Missense Mutation (SNP) | VAF 86/324 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SRFBP1 | c.1034T>G p.F345C | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TAF4 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 159/397 reads (40%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TBC1D23 | c.532C>T p.H178Y | Missense Mutation (SNP) | VAF 88/171 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TC2N | c.317C>G p.S106C | Missense Mutation (SNP) | VAF 131/218 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- TCEANC2 | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TENM2 | c.2892G>T p.Q964H (on ENST00000518659 / NM_001122679.2; = p.Q732H on NM_001080428.3) | Missense Mutation (SNP) | VAF 117/363 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- THAP9 | c.2458C>G p.H820D | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- THUMPD3 | c.1177C>G p.L393V | Missense Mutation (SNP) | VAF 82/162 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, varscan2
- TLK1 | c.1849G>C p.D617H | Missense Mutation (SNP) | VAF 46/242 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TLN2 | c.5497G>T p.A1833S | Missense Mutation (SNP) | VAF 144/297 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMPRSS2 | c.441del p.C148Vfs*53 | Frame Shift Del (DEL) | VAF 104/760 reads (14%) | called by mutect2, pindel, varscan2
- TNIK | c.47C>G p.S16W | Missense Mutation (SNP) | VAF 118/399 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by mutect2, varscan2
- TTC37 | c.339G>T p.Q113H | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- UPK2 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 115/454 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- USP45 | c.1190G>A p.R397K | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- VRK2 | c.607C>T p.Q203* | Nonsense Mutation (SNP) | VAF 142/374 reads (38%) | called by muse, mutect2, varscan2
- YJU2 | c.349G>C p.E117Q | Missense Mutation (SNP) | VAF 168/384 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ZFC3H1 | c.2855C>G p.S952* | Nonsense Mutation (SNP) | VAF 32/182 reads (18%) | called by muse, mutect2, varscan2
- ZFHX4 | c.10636C>A p.P3546T | Missense Mutation (SNP) | VAF 111/1049 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- ZNF273 | c.538T>C p.C180R | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- ZNF324 | c.1652_1653insCGGC p.E552Gfs*84 | Frame Shift Ins (INS) | VAF 117/580 reads (20%) | called by mutect2, pindel, varscan2
- ZNF439 | c.1114C>T p.H372Y | Missense Mutation (SNP) | VAF 59/171 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- ZNF442 | c.1470T>G p.C490W | Missense Mutation (SNP) | VAF 74/155 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACOD1 | c.1185A>C p.G395= | Silent (SNP) | VAF 127/268 reads (47%) | catalogued as rs1332565244; called by muse, mutect2, varscan2
- AF196969.1 | c.234G>A p.V78= | Silent (SNP) | VAF 213/213 reads (100%) | catalogued as CD991690; called by muse, mutect2, varscan2
- AICDA | c.186C>G p.L62= | Silent (SNP) | VAF 113/336 reads (34%) | catalogued as COSV57563546; called by muse, mutect2, varscan2
- BEST1 | c.543C>T p.F181= | Silent (SNP) | VAF 158/544 reads (29%) | catalogued as COSV57120093; called by muse, mutect2, varscan2
- BICD2 | c.561G>A p.E187= | Silent (SNP) | VAF 118/454 reads (26%) | catalogued as COSV63549714; called by muse, mutect2, varscan2
- BICRAL | c.2970C>T p.I990= | Silent (SNP) | VAF 154/433 reads (36%) | called by muse, mutect2, varscan2
- BTNL8 | c.1377C>T p.I459= | Silent (SNP) | VAF 168/536 reads (31%) | catalogued as COSV99180472; called by muse, mutect2, varscan2
- C6orf118 | c.540C>T p.P180= | Silent (SNP) | VAF 177/576 reads (31%) | catalogued as rs145574207, COSV57815725; called by muse, mutect2, varscan2
- CACNA1D | c.291G>C p.S97= | Silent (SNP) | VAF 349/349 reads (100%) | catalogued as COSV55451743; called by muse, mutect2, varscan2
- CACNA1D | c.3282C>G p.L1094= (on ENST00000350061 / NM_001128840.3; = p.L1114= on NM_000720.4) | Silent (SNP) | VAF 171/349 reads (49%) | called by muse, mutect2, varscan2
- CARD9 | c.357G>A p.L119= | Silent (SNP) | VAF 162/472 reads (34%) | called by muse, mutect2, varscan2
- CCDC80 | c.306G>A p.V102= | Silent (SNP) | VAF 37/912 reads (4%) | catalogued as COSV52816326; called by muse, mutect2
- CD22 | c.1932G>A p.L644= | Silent (SNP) | VAF 261/771 reads (34%) | called by muse, mutect2, varscan2
- CD300H | c.177A>G p.Q59= | Silent (SNP) | VAF 130/542 reads (24%) | called by muse, mutect2, varscan2
- CDH5 | c.2085G>A p.A695= | Silent (SNP) | VAF 314/925 reads (34%) | catalogued as rs374977157; called by muse, mutect2, varscan2
- CDK2AP2 | c.72G>T p.P24= | Silent (SNP) | VAF 228/844 reads (27%) | catalogued as rs1260361385; called by muse, mutect2, varscan2
- CERS1 | c.777C>T p.F259= | Silent (SNP) | VAF 140/370 reads (38%) | called by muse, mutect2, varscan2
- CHRNB2 | c.201C>T p.L67= | Silent (SNP) | VAF 120/464 reads (26%) | catalogued as rs773706734; ClinVar: likely benign; called by muse, mutect2, varscan2
- ENTPD8 | c.885C>G p.A295= | Silent (SNP) | VAF 264/822 reads (32%) | called by muse, mutect2, varscan2
- ESYT1 | c.315G>A p.A105= | Silent (SNP) | VAF 237/688 reads (34%) | catalogued as rs1346157398, COSV57274810; called by muse, mutect2, varscan2
- F7 | c.117G>A p.P39= | Silent (SNP) | VAF 155/327 reads (47%) | catalogued as rs780290098; called by muse, mutect2, varscan2
- FZD3 | c.99G>A p.L33= | Silent (SNP) | VAF 101/101 reads (100%) | catalogued as COSV53538026, COSV99527986; called by muse, mutect2, varscan2
- GAB1 | c.1176T>C p.D392= | Silent (SNP) | VAF 70/295 reads (24%) | called by muse, mutect2, varscan2
- GAL3ST2 | c.906G>A p.R302= | Silent (SNP) | VAF 362/1094 reads (33%) | called by muse, mutect2, varscan2
- GALNTL5 | c.1119C>T p.I373= | Silent (SNP) | VAF 92/344 reads (27%) | catalogued as COSV67179152; called by muse, mutect2, varscan2
- GPR17 | c.996C>T p.F332= | Silent (SNP) | VAF 224/679 reads (33%) | called by muse, mutect2, varscan2
- H2AC11 | c.303C>T p.V101= | Silent (SNP) | VAF 159/428 reads (37%) | catalogued as rs758805616; called by muse, mutect2, varscan2
- HACD2 | c.429C>T p.I143= | Silent (SNP) | VAF 60/441 reads (14%) | called by muse, mutect2, varscan2
- HMCN1 | c.15465G>A p.R5155= | Silent (SNP) | VAF 116/504 reads (23%) | called by muse, mutect2, varscan2
- HMCN2 | c.14562C>T p.F4854= | Silent (SNP) | VAF 175/545 reads (32%) | catalogued as rs1246995787; called by muse, mutect2, varscan2
- HSPA6 | c.54G>C p.S18= | Silent (SNP) | VAF 120/413 reads (29%) | called by muse, mutect2, varscan2
- IFITM3 | c.324C>T p.I108= | Silent (SNP) | VAF 203/475 reads (43%) | catalogued as rs1060603; called by muse, mutect2, varscan2
- ITPR3 | c.7962G>A p.R2654= | Silent (SNP) | VAF 145/526 reads (28%) | called by muse, mutect2, varscan2
- JMJD4 | c.843C>G p.L281= | Silent (SNP) | VAF 256/1117 reads (23%) | catalogued as COSV59916742; called by muse, mutect2, varscan2
- JUP | c.2145G>A p.E715= | Silent (SNP) | VAF 250/1320 reads (19%) | catalogued as rs371395790; called by muse, mutect2, varscan2
- KCNF1 | c.891C>T p.I297= | Silent (SNP) | VAF 340/1298 reads (26%) | catalogued as rs559871658, COSV54462612; called by muse, mutect2, varscan2
- KDM4B | c.2667C>T p.L889= | Silent (SNP) | VAF 291/586 reads (50%) | catalogued as COSV99345884; called by muse, mutect2, varscan2
- KRT34 | c.222T>C p.P74= | Silent (SNP) | VAF 362/2051 reads (18%) | catalogued as rs569964224; called by muse, mutect2, varscan2
- MALL | c.123C>G p.V41= | Silent (SNP) | VAF 169/576 reads (29%) | catalogued as COSV55600933; called by muse, mutect2, varscan2
- MICA | c.99G>A p.T33= | Silent (SNP) | VAF 148/519 reads (29%) | catalogued as rs747747009; called by muse, mutect2, varscan2
- MTREX | c.2166G>A p.E722= | Silent (SNP) | VAF 63/139 reads (45%) | called by muse, mutect2, varscan2
- MTUS2 | c.2091G>A p.E697= | Silent (SNP) | VAF 166/344 reads (48%) | catalogued as rs1167327375; called by muse, mutect2, varscan2
- NUSAP1 | c.717C>G p.L239= | Silent (SNP) | VAF 162/480 reads (34%) | called by muse, mutect2, varscan2
- OR3A1 | c.450G>A p.A150= | Silent (SNP) | VAF 696/696 reads (100%) | catalogued as rs779127412, COSV60163544; called by muse, mutect2, varscan2
- OR5M11 | c.543G>A p.P181= | Silent (SNP) | VAF 157/483 reads (33%) | catalogued as rs979783807, COSV73141942; called by muse, mutect2, varscan2
- OTOA | c.552G>C p.L184= | Silent (SNP) | VAF 153/499 reads (31%) | called by muse, mutect2, varscan2
- PCDHB2 | c.1554C>T p.L518= | Silent (SNP) | VAF 302/989 reads (31%) | called by muse, varscan2
- PDE4A | c.1668G>A p.L556= (on ENST00000380702 / NM_001111307.2; = p.L317= on NM_006202.3) | Silent (SNP) | VAF 189/408 reads (46%) | catalogued as COSV53351751; called by muse, mutect2, varscan2
- PGR | c.1935C>T p.V645= | Silent (SNP) | VAF 182/282 reads (65%) | called by muse, varscan2
- PHIP | c.4485C>T p.N1495= | Silent (SNP) | VAF 130/384 reads (34%) | catalogued as rs1474049210, COSV51502489; called by muse, mutect2, varscan2
- PIK3R4 | c.2311C>T p.L771= | Silent (SNP) | VAF 69/438 reads (16%) | called by muse, mutect2, varscan2
- PITPNM2 | c.3859C>T p.L1287= | Silent (SNP) | VAF 286/957 reads (30%) | called by muse, mutect2, varscan2
- PIWIL4 | c.1899G>A p.V633= | Silent (SNP) | VAF 90/394 reads (23%) | catalogued as rs773701114; called by muse, mutect2, varscan2
- PNPLA2 | c.1413C>G p.P471= | Silent (SNP) | VAF 438/930 reads (47%) | catalogued as rs540018341; called by muse, mutect2, varscan2
- PNPLA7 | c.2754G>A p.A918= | Silent (SNP) | VAF 221/761 reads (29%) | catalogued as rs535218909; called by muse, mutect2, varscan2
- POLR1A | c.4677C>T p.I1559= | Silent (SNP) | VAF 168/803 reads (21%) | catalogued as rs1488385494; called by muse, mutect2, varscan2
- PTPRT | c.3546C>T p.L1182= | Silent (SNP) | VAF 102/344 reads (30%) | called by muse, mutect2, varscan2
- PXMP4 | c.594C>T p.D198= | Silent (SNP) | VAF 122/405 reads (30%) | called by muse, mutect2, varscan2
- SAGE1 | c.381C>G p.V127= | Silent (SNP) | VAF 140/664 reads (21%) | called by muse, mutect2, varscan2
- SEC16B | c.2709G>A p.G903= | Silent (SNP) | VAF 93/382 reads (24%) | called by muse, mutect2, varscan2
- SEMA6B | c.870C>G p.L290= | Silent (SNP) | VAF 312/638 reads (49%) | called by muse, mutect2, varscan2
- SLC16A1 | c.204C>G p.V68= | Silent (SNP) | VAF 89/291 reads (31%) | called by muse, mutect2, varscan2
- SLC4A4 | c.334C>T p.L112= (on ENST00000264485 / NM_001098484.3; = p.L68= on NM_003759.4) | Silent (SNP) | VAF 145/636 reads (23%) | called by muse, mutect2, varscan2
- SLC6A6 | c.1302C>T p.F434= | Silent (SNP) | VAF 170/340 reads (50%) | catalogued as rs751612848; called by muse, mutect2, varscan2
- SLCO1C1 | c.1773C>T p.I591= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as COSV56875791, COSV99859852; called by muse, mutect2, varscan2
- SPTBN1 | c.414C>A p.I138= | Silent (SNP) | VAF 325/710 reads (46%) | called by muse, mutect2, varscan2
- STK19 | c.681C>G p.L227= (on ENST00000375333 / NM_032454.1; = p.L223= on NM_004197.1) | Silent (SNP) | VAF 121/321 reads (38%) | called by muse, mutect2, varscan2
- TLNRD1 | c.394C>T p.L132= | Silent (SNP) | VAF 312/929 reads (34%) | catalogued as rs747927954, COSV51256815, COSV51257583; called by muse, mutect2, varscan2
- TMC6 | c.756C>G p.L252= | Silent (SNP) | VAF 32/674 reads (5%) | catalogued as COSV100129871; called by muse, mutect2
- TMCC2 | c.1326C>T p.I442= | Silent (SNP) | VAF 244/958 reads (25%) | catalogued as rs774057777; called by muse, mutect2, varscan2
- TRABD2A | c.120G>A p.L40= | Silent (SNP) | VAF 101/461 reads (22%) | called by muse, mutect2, varscan2
- TUBA4B | c.453C>T p.I151= | Silent (SNP) | VAF 197/635 reads (31%) | called by muse, mutect2, varscan2
- USP38 | c.588A>C p.T196= | Silent (SNP) | VAF 180/687 reads (26%) | called by muse, mutect2, varscan2
- WDR33 | c.297G>A p.L99= | Silent (SNP) | VAF 4/49 reads (8%) | catalogued as rs1374466993, COSV100460235; called by muse, mutect2
- ZNRF4 | c.18G>A p.P6= | Silent (SNP) | VAF 130/266 reads (49%) | catalogued as rs369224291, COSV55773227; called by muse, mutect2, varscan2
- COL6A5 | c.*652G>C | 3'UTR (SNP) | VAF 138/178 reads (78%) | catalogued as rs1001239484; called by muse, mutect2, varscan2
- DCHS2 | n.8305C>T | RNA (SNP) | VAF 92/507 reads (18%) | called by muse, mutect2, varscan2
- DCHS2 | n.6924G>C | RNA (SNP) | VAF 106/470 reads (23%) | catalogued as COSV104421295; called by muse, mutect2, varscan2
- FSD2 | chr15:82750784 C>G | 3'Flank (SNP) | VAF 204/564 reads (36%) | called by muse, mutect2, varscan2
- GC | c.*60G>C | 3'UTR (SNP) | VAF 67/379 reads (18%) | called by muse, mutect2, varscan2
- HAPLN3 | c.-48+2457G>C | Intron (SNP) | VAF 115/434 reads (26%) | catalogued as rs1386576534; called by muse, mutect2
- IQCK | c.802+16C>T | Intron (SNP) | VAF 120/530 reads (23%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+3100C>T | Intron (SNP) | VAF 169/322 reads (52%) | called by muse, mutect2, varscan2
- LDB2 | c.891+2656G>A | Intron (SNP) | VAF 104/239 reads (44%) | called by muse, mutect2, varscan2
- MIR9-1HG | n.583G>C | RNA (SNP) | VAF 75/302 reads (25%) | catalogued as COSV59485274; called by muse, mutect2, varscan2
- SPRED3 | chr19:38388668 C>G | 5'Flank (SNP) | VAF 125/423 reads (30%) | called by muse, mutect2, varscan2
- ZSCAN1 | c.370+67C>T | Intron (SNP) | VAF 225/1015 reads (22%) | called by muse, mutect2, varscan2
